Gene-level copy-number profile of tumor specimen HCM-SANG-0297-C15-01A from HCMI case HCM-SANG-0297-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-0297-C15-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b17a0189-c126-4f6f-a8ae-d630239ec66f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0297-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,738 have no estimate.
https://portal.gdc.cancer.gov/files/f8bfd71c-33d0-4648-90f9-c9e5897d0020

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 201; copy number 1: 20,672; copy number 2: 32,420; copy number 3: 3,900; copy number 4: 1,088; copy number 5: 69; copy number 6: 234; copy number 8: 148; copy number 9: 15; copy number 10: 67; copy number 11: 71.

Homozygous deletions (total copy number 0; autosomes only): 201 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–49,589,529, 12 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr4:132,591,064–132,678,503, 2 genes (within-gene range 0–1): LINC01256, AARS1P1.
- chr4:134,026,665–134,327,977, 1 gene (within-gene range 0–1): AC015631.1.
- chr4:134,327,063–136,395,471, 19 genes: PES1P1, LINC02462, AC093722.1, AC104619.2, AC104619.4, AC104619.1, AC104619.3, AC107463.1, LINC02485, KRT18P54, TARS2P1, AC105362.1, LINC00613, RNU1-89P, AC104136.1, AC073429.2, AC018680.1, AC073429.1, TERF1P3.
- chr4:162,022,733–162,047,567, 1 gene (within-gene range 0–2): AC023136.1.
- chr8:76,162,119–76,308,315, 2 genes: AC011029.1, RNU2-54P.
- chr9:95,859,904–95,860,016, 1 gene (within-gene range 0–2): RNU2-46P.
- chr9:102,922,574–102,923,244, 1 gene: AL365396.1.
- chr14:26,443,090–26,598,033, 2 genes: NOVA1, AL079343.1.
- chr21:16,862,875–22,420,819, 63 genes (broad region; genes not listed).
- chr21:22,882,582–22,884,000, 1 gene: AP000949.1.
- chr22:15,282,557–17,132,104, 82 genes (broad region; genes not listed).
- chr22:18,501,794–18,653,617, 13 genes: FAM247B, GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B, PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2.
- chr22:48,448,890–48,451,217, 1 gene: Z82249.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 604 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:47,231,532–47,832,780, 13 genes, copy number 6–9: TNFRSF21, B3GNTL1P2, AL355353.1, CD2AP, Y_RNA, AL358178.1, ADGRF2, ADGRF4, RN7SKP116, AL356421.2, AL356421.1, OPN5, RNU1-105P.
- chr11:67,583,742–67,784,229, 17 genes, copy number 11: GSTP1, C11orf72, AP003385.3, NDUFV1, DOC2GP, NUDT8, TBX10, ACY3, AP003385.1, ALDH3B2, RPL37P2, UNC93B5, OR7E145P, OR7E11P, AP003385.5, AP003385.2, AP003385.4.
- chr11:68,980,021–76,444,687, 259 genes, copy number 6–11 (broad region; genes not listed).
- chr11:76,654,169–83,423,516, 107 genes, copy number 6–9 (broad region; genes not listed).
- chr11:107,326,345–109,823,893, 38 genes, copy number 6: CWF19L2, SMARCE1P1, ALKBH8, AP001823.1, ELMOD1, AP000889.2, AP000889.1, SLN, AP002353.1, SLC35F2, AP001024.1, RAB39A, AP003307.1, CUL5, Y_RNA, AP002433.1, ACAT1, AP002433.2, NPAT, ATM, Y_RNA, C11orf65, POGLUT3, EXPH5, DDX10, RPS2P39, AP002453.1, CYCSP29, AP003027.1, AP003123.1, RNU6-654P, RNA5SP349, SNORD39, AP003049.2, C11orf87, AP003049.1, AP003102.1, LINC02715.
- chr11:114,343,052–114,454,123, 6 genes, copy number 8 (within-gene range 1–8): AP002518.1, C11orf71, RBM7, AP002373.1, REXO2, AP002373.2.
- chr11:117,427,772–119,381,711, 94 genes, copy number 6–10 (broad region; genes not listed).
- chr11:119,372,706–119,381,613, 1 gene, copy number 6: AP003396.3.
- chr17:71,596,338–73,092,712, 18 genes, copy number 5: AC118653.1, MYL6P5, ROCR, LINC01152, AC007461.1, SOX9-AS1, LINC02097, SOX9, LINC00511, LINC02003, AC007639.1, RPL32P33, AC080037.2, SLC39A11, RN7SKP180, AC080037.1, AC011120.1, ATG12P1.
- chr18:21,612,314–23,672,748, 51 genes, copy number 5: SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA, CABLES1, TMEM241, AC011731.1, RIOK3, Y_RNA, AC026634.1, RMC1, NPC1, Y_RNA, ANKRD29, RPS10P27.

Autosomal genes at a single copy (total copy number 1): 20,060. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
